Gene-level copy-number profile of tumor specimen C3N-00871-01 (profiled together with C3N-00871-02) from CPTAC case C3N-00871, project CPTAC-3 (Other and ill-defined sites in lip, oral cavity and pharynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 58.8 years (21,468 days).
Specimen C3N-00871-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Oral Cavity; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9485cd6f-c0a4-4902-9e29-1a3806616fda.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00871-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/9ffce4a6-5800-45a0-9215-2f06ae372c12

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 56; copy number 1: 319; copy number 2: 14,867; copy number 3: 1,272; copy number 4: 33,993; copy number 5: 192; copy number 6: 7,731; copy number 7: 78; copy number 8: 38; copy number 9: 5; copy number 10: 292; copy number 11: 51; copy number 14: 3; copy number 21: 8.

Homozygous deletions (total copy number 0; autosomes only): 47 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,384,059–75,580,199, 10 genes: AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10, AC133041.1, RPS3AP15.
- chr4:49,548,564–49,589,529, 7 genes: AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr4:186,890,969–187,517,208, 11 genes: AC108865.1, AC108865.2, MRPS36P2, AC110772.1, AC110772.2, LINC02374, AC097652.1, LINC02514, LINC02515, AC093763.2, AC093763.1.
- chr7:111,091,006–111,125,454, 1 gene (within-gene range 0–2): LRRN3.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–2): AL359922.1.
- chr9:21,929,457–22,128,103, 9 genes (within-gene range 0–2): ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr15:63,189,560–63,309,126, 2 genes: RAB8B, APH1B.
- chr17:18,426,861–18,506,313, 6 genes (within-gene range 0–3): KRT17P2, KRT16P1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 359 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:169,286,534–170,738,536, 35 genes, copy number 11: BX322234.2, VTA1P1, LINC02519, AL031315.1, AL135910.1, WDR27, C6orf120, PHF10, AL354892.2, AL354892.1, TCTE3, ERMARD, AL354892.3, LINC00242, LINC00574, AL049612.1, AL596442.1, AL596442.2, RPL12P23, AL109910.1, AL109910.2, LINC01624, DLL1, FAM120B, AL078605.1, MIR4644, AL008628.1, PSMB1, TBP, PDCD2, AL672310.1, OR4F7P, WBP1LP8, AL731661.1, AL731684.1.
- chr11:101,451,564–101,872,562, 1 gene, copy number 14 (within-gene range 6–21): TRPC6.
- chr11:101,584,295–102,727,050, 26 genes, copy number 11–21: AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8.
- chr11:124,376,877–124,424,893, 5 genes, copy number 9: OR8C1P, OR8B2, OR8B3, OR8X1P, OR8B4.
- chr18:20,946,906–44,071,701, 292 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 317. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
